Somatic mutation profile of tumor specimen C3L-01836-02 (aliquot CPT0086870009) from CPTAC case C3L-01836, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 47.1 years (17,215 days).
Specimen C3L-01836-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9506506c-28cf-407d-9621-6ca6f7e6fd7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01836-31 (Blood Derived Normal), aliquot CPT0087440002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6d197df-6215-4753-aa73-c40738ac8089

The open-access MAF lists 29 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 6, Frame Shift Ins 2, Intron 2, 5'UTR 2, In Frame Del 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP95 | c.1540G>T p.E514* | Nonsense Mutation (SNP) | VAF 17/75 reads (23%) | catalogued as COSV101616285; called by muse, varscan2
- EDNRB | c.478G>A p.E160K (on ENST00000377211 / NM_001201397.1; = p.E70K on NM_000115.5) | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.048); catalogued as rs748181676; called by muse, mutect2
- INHBE | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 56/278 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.069); catalogued as rs372615182; called by muse, mutect2, varscan2
- OR2M5 | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 54/267 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.452); catalogued as COSV100822754; called by muse, mutect2, varscan2
- PBRM1 | c.1925-1G>A p.X642_splice | Splice Site (SNP) | VAF 8/29 reads (28%) | catalogued as COSV56267332; called by muse, varscan2
- SUN5 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs376507648; called by muse, mutect2, varscan2
- TP53 | c.607G>C p.V203L | Missense Mutation (SNP) | VAF 84/655 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs730882003, COSV52761693, COSV52809012, COSV52965683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGTRAP | c.143G>C p.R48P | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ATIC | c.1297G>A p.V433M | Missense Mutation (SNP) | VAF 175/726 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- CYB5R4 | c.1053G>T p.L351F | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- KLHL30 | c.896_898del p.N299del | In Frame Del (DEL) | VAF 10/36 reads (28%) | called by pindel, varscan2
- LRRK2 | c.317dup p.N107Kfs*2 | Frame Shift Ins (INS) | VAF 61/326 reads (19%) | called by mutect2, pindel, varscan2
- LYST | c.10406G>T p.W3469L | Missense Mutation (SNP) | VAF 49/224 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- NEURL1B | c.240G>T p.E80D | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH17 | c.2169G>A p.M723I | Missense Mutation (SNP) | VAF 53/230 reads (23%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- POLR2B | c.2416T>G p.F806V | Missense Mutation (SNP) | VAF 47/306 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- VHL | c.168_169dup p.G57Afs*11 | Frame Shift Ins (INS) | VAF 43/185 reads (23%) | called by mutect2, pindel, varscan2
- ZNF324 | c.234C>A p.N78K | Missense Mutation (SNP) | VAF 56/253 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF671 | c.1259C>G p.T420S | Missense Mutation (SNP) | VAF 59/307 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- DCAF8L1 | c.141G>A p.S47= | Silent (SNP) | VAF 67/175 reads (38%) | catalogued as rs760112871, COSV101491428, COSV101491459; called by muse, mutect2, varscan2
- MUC5B | c.7140C>T p.S2380= | Silent (SNP) | VAF 28/466 reads (6%) | called by muse, mutect2
- PHLDB3 | c.1503C>T p.P501= | Silent (SNP) | VAF 53/164 reads (32%) | catalogued as rs1210066990; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2199G>A p.G733= | Silent (SNP) | VAF 34/630 reads (5%) | catalogued as rs1162476645; called by muse, mutect2
- ZNF227 | c.585T>A p.I195= | Silent (SNP) | VAF 51/225 reads (23%) | called by muse, mutect2, varscan2
- ZNF721 | c.762A>G p.K254= (on ENST00000338977; = p.K266= on NM_133474.4) | Silent (SNP) | VAF 66/316 reads (21%) | catalogued as rs781912933; called by muse, mutect2, varscan2
- CUBN | c.-37G>A | 5'UTR (SNP) | VAF 64/354 reads (18%) | called by muse, mutect2, varscan2
- DNM1L | c.1540-40del | Intron (DEL) | VAF 49/190 reads (26%) | called by mutect2, pindel, varscan2
- FSTL1 | c.331+106C>A | Intron (SNP) | VAF 91/588 reads (15%) | called by muse, mutect2, varscan2
- ZNF417 | c.-25G>A | 5'UTR (SNP) | VAF 46/213 reads (22%) | catalogued as rs773481811; called by muse, mutect2, varscan2
